CCDI case PBCAKN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/40d94511-88bc-4f47-9e35-d0bc6b24c64d

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Rhabdoid tumor, NOS: ICD-O-3 morphology code: 8963/3; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 16.7 years (6,106 days).

Biospecimens (3 samples)
- Sample 0DMWTM: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMWTS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DMWTY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
